CCDI case PBBXIK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/01821dcc-4b48-4d4e-907a-9154a2c7657e

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 14.6 years (5,349 days).

Biospecimens (4 samples)
- Samples 0DKWN0, 0DKWNA (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DKWNN: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLHOV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
